Gene-level copy-number profile of tumor specimen TCGA-13-0762-01A from TCGA case TCGA-13-0762, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.6 years (23,960 days).
Specimen TCGA-13-0762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a34ce5b9-fc4a-44ce-b89c-e8bcba934913.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0762-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3d21a1d-b8b4-4336-846e-0ce30a0bdae6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 20; copy number 2: 6,759; copy number 3: 9,670; copy number 4: 12,221; copy number 5: 9,097; copy number 6: 12,053; copy number 7: 4,233; copy number 8: 3,703; copy number 9: 1,174; copy number 10: 107; copy number 11: 197; copy number 12: 40; copy number 15: 101; copy number 16: 330; copy number 21: 41; copy number 23: 49; copy number 25: 3; copy number 30: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0762-01): tumor purity 0.78, ploidy 4.8, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,055 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,926,831–248,919,946, 268 genes, copy number 11–16 (broad region; genes not listed).
- chr6:47,878,028–50,181,007, 31 genes, copy number 10 (within-gene range 7–10): PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr6:60,719,222–62,286,225, 10 genes, copy number 10 (within-gene range 6–10): GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr8:53,388,701–71,228,629, 277 genes, copy number 15–30 (within-gene range 3–30) (broad region; genes not listed).
- chr11:76,381,303–79,612,300, 70 genes, copy number 12–23 (broad region; genes not listed).
- chr11:80,751,200–88,428,176, 122 genes, copy number 11 (broad region; genes not listed).
- chr12:66,767–47,279,021, 984 genes, copy number 9–12 (broad region; genes not listed).
- chr12:48,147,789–48,181,213, 1 gene, copy number 9 (within-gene range 8–9): ASB8.
- chr12:48,168,847–51,324,668, 153 genes, copy number 9 (broad region; genes not listed).
- chr15:25,902,119–26,053,123, 1 gene, copy number 12 (within-gene range 5–12): LINC02346.
- chr15:26,008,940–27,685,768, 24 genes, copy number 12: AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1, GABRG3, GABRG3-AS1, AC136896.1, RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2, AC104002.3, AC021979.1, AC021979.3, AC021979.2.
- chr15:27,775,621–27,776,798, 1 gene, copy number 12: AC090696.1.
- chr19:21,677,550–24,163,425, 113 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
